Somatic mutation profile of tumor specimen 0DUIX9 from CCDI case PBCLHE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.0 years (3,654 days).
Specimen 0DUIX9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 407045a4-5c54-4083-87fc-9bcdd68d3e92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUIWQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49c803a3-f33d-4d5d-bf37-d81cbc58e787

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, 5'UTR 2, 3'UTR 1, Frame Shift Del 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 235/564 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 139/449 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 103/257 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BLVRA | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 275/698 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201354201, COSV55512679; called by muse, mutect2, varscan2
- DNAH8 | c.3959G>A p.R1320H | Missense Mutation (SNP) | VAF 215/642 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs375507271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTRA3 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 142/366 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745448154, COSV56470594; called by mutect2, varscan2
- KDR | c.4060C>A p.P1354T | Missense Mutation (SNP) | VAF 66/1052 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); catalogued as COSV55774157; called by muse, mutect2
- OR7A17 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as rs749086811; called by muse, mutect2, varscan2
- ARHGAP30 | c.1769C>A p.S590Y | Missense Mutation (SNP) | VAF 33/658 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- C6 | c.2188C>G p.L730V | Missense Mutation (SNP) | VAF 126/262 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CPSF7 | c.671del p.Y224Sfs*11 (on ENST00000394888 / NM_001136040.4; = p.Y267Sfs*11 on NM_024811.4) | Frame Shift Del (DEL) | VAF 58/143 reads (41%) | called by mutect2, varscan2
- PCDHGB2 | c.2377C>A p.H793N | Missense Mutation (SNP) | VAF 165/422 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDGFRB | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 126/407 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PYHIN1 | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 24/838 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); called by muse, mutect2
- SULT1A1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0.018); called by muse, mutect2
- CR1 | c.5754C>T p.I1918= | Silent (SNP) | VAF 112/516 reads (22%) | called by muse, mutect2, varscan2
- DUSP9 | c.54G>A p.P18= | Silent (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2, varscan2
- PDE3B | c.1317G>A p.R439= | Silent (SNP) | VAF 98/1326 reads (7%) | called by muse, mutect2
- CHORDC1 | c.-92C>G | 5'UTR (SNP) | VAF 25/37 reads (68%) | called by muse, mutect2, varscan2
- DIP2C | c.-37A>T | 5'UTR (SNP) | VAF 3/24 reads (13%) | called by muse, varscan2
- KCTD6 | c.*85A>C | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- MCF2 | chrX:139646895 C>T | 5'Flank (SNP) | VAF 18/280 reads (6%) | catalogued as COSV58492002; called by muse, mutect2
- XG | c.409+67G>T | Intron (SNP) | VAF 92/127 reads (72%) | called by muse, mutect2, varscan2
